Somatic mutation profile of tumor specimen 0DEV49 from CCDI case PBBLYY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.3 years (5,574 days).
Specimen 0DEV49: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c920c2fa-bba8-4cb7-a37c-afbfddb67dd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV28 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/998215aa-cdac-4b6f-98ab-409f8ef44a23

The open-access MAF lists 20 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 7, Missense Mutation 4, 5'UTR 4, Silent 3, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4560+3del | Splice Region (DEL) | VAF 20/113 reads (18%) | catalogued as COSV52132141; called by mutect2, varscan2
- CYSLTR1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200459301, COSV64820103; called by muse, varscan2
- LRIG2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- SLC26A1 | c.1574C>A p.A525D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, varscan2
- WNK1 | c.4831C>T p.P1611S (on ENST00000315939 / NM_018979.4; = p.P1364S on NM_014823.3) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.946); called by muse, varscan2
- CSMD2 | c.522C>T p.H174= | Silent (SNP) | VAF 34/214 reads (16%) | catalogued as rs749023926, COSV53912233, COSV53919670; called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- PLXNA3 | c.840C>T p.I280= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as rs149751983, COSV63753205; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, varscan2
- GSDME | c.698-47C>T | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
- IBTK | c.3798-42A>T | Intron (SNP) | VAF 6/47 reads (13%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- NMUR2 | c.-74C>T | 5'UTR (SNP) | VAF 20/120 reads (17%) | catalogued as rs78434432; called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 14/100 reads (14%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 13/89 reads (15%) | called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2, varscan2
- SGK1 | c.662+60G>A | Intron (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- SIMC1 | c.1677+98T>C | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as COSV104418257; called by muse, varscan2
- SLC36A3 | c.-210G>C | 5'UTR (SNP) | VAF 12/74 reads (16%) | catalogued as rs1182246468; called by muse, mutect2, varscan2
- VPS50 | c.422+64_422+65insCATAATTTAAAAAATCAAT | Intron (INS) | VAF 5/34 reads (15%) | called by mutect2, varscan2*
